Gene-level copy-number profile of tumor specimen TCGA-KK-A59Z-01A from TCGA case TCGA-KK-A59Z, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,306 days).
Specimen TCGA-KK-A59Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.7ed89165-c878-4c8e-99b7-df3ac2351d84.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A59Z-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/51956e03-0fed-45fe-b9f2-d10b2c2633a7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 23; copy number 2: 4,907; copy number 3: 11,258; copy number 4: 29,824; copy number 5: 5,839; copy number 6: 3,262; copy number 7: 2,827; copy number 9: 794; copy number 10: 998.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A59Z-01A-12D-A26L-01): tumor purity 0.8, ploidy 4.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:18,704,433–18,746,173, 1 gene: LINC02100.
- chr5:97,089,075–97,437,217, 1 gene (within-gene range 0–2): LIX1-AS1.
- chr5:97,183,827–97,216,074, 1 gene (within-gene range 0–2): AC008883.3.
- chr5:97,223,371–100,903,282, 59 genes: AC008883.2, AC074133.1, YTHDF1P1, AC106748.1, LINC01340, MTCYBP40, AC112203.1, AC122697.1, LINC02234, AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P.
- chr10:55,599,042–56,364,714, 5 genes: MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,792 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,926,689, 57 genes, copy number 9: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr8:33,969,567–145,066,685, 1,735 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
